Surgical pathology report (de-identified scan), TCGA case TCGA-HU-A4GN, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site National Cancer Center Korea, specimen TCGA-HU-A4GN-01A (Primary Tumor).

[page 1 of 3]
GROSS:

Specimen state: Fresh

Operation: Distal gastrectomy

Measurement: Greater curvature 15.5 cm

Lesser curvature 14.4 cm

Proximal resection margin 18.3 cm

Distal resection margin 6.0 cm

Duodenum 0.8 cm

Lesion: Ulceroinfiltrative mass

Tumor size: 5.3 x 4.0 x 0.5 cm

Location: Anterior wall of proximal antrum

Tumor type: AGC (Borrmann type III)

From proximal resection margin - 7.1 cm

From distal resection margin - 4.6 cm

Gross serosal invasion: No

Blocks

T1-4 and TB, tumor and surrounding tissue x 5

A, antral mucosa x 1

B and NB, body mucosa x 2

P, proximal resection margin x 1

D, distal resection margin of resected specimen x 1

DRM, labeled as 'distal margin' x 1

LN1-2, superior gastric lymph nodes x 2

LN3-4, inferior gastric lymph nodes x 2

LN5, '1' lymph nodes x 1

LN6, '4sb' lymph nodes x 1

LN7, '5' lymph nodes x 1

LN8, '6' lymph nodes x 1

LN9, '7' lymph nodes x 1

LN10-11, '8' lymph nodes x 2

LN12, '9' lymph nodes x 1

LN13-14, '11p' lymph nodes x 2

LN15, '12' lymph nodes x 1

ICD-0-3

adenocarcinoma, tubular 8211/3

Site: Stomach, antrum C16.3

pw
9/27/12

MICROSCOPIC:

Tumor type: Adenocarcinoma

Differentiation: Moderately differentiated

[page 2 of 3]
Depth of tumor invasion:

T2: Tumor invades muscularis propria

Margins: Proximal resection margin (-)

Distal resection margin (-)

Lauren classification: Intestinal

Ming classification (Growth pattern): Infiltrative

Stromal reaction: Heavy acute and chronic inflammatory cells infiltrates

Lymphovascular invasion: Present

Venous (large vessel) invasion: Absent

Perineural invasion: Absent

Lymph node metastasis: Present

DIAGNOSIS:

Stomach, distal gastrectomy:

Adenocarcinoma, moderately differentiated, infiltrating
(advanced gastric cancer)

<Addendum>

Final diagnosis: Stomach Intestinal Adenocarcinoma, Tubular Type *per clarification by TSS.*

Lymph node, perigastric, distal gastrectomy:

Superior gastric: Metastatic carcinoma, primary in stomach (1/13)

Inferior gastric: No tumor present (0/7)

Lymph node, regional, biopsy:

Labeled as '1': No lymphoid tissue

Labeled as '4sb': No tumor present (0/2)

Labeled as '5': No tumor present (0/1)

Labeled as '6': No tumor present (0/3)

Labeled as '7': No tumor present (0/1)

Labeled as '8': No tumor present (0/9)

Labeled as '9': No tumor present (0/1)

Labeled as '11p': No tumor present (0/9)

Labeled as '12': No tumor present (0/1)

[page 3 of 3]
Lymph node, regional, biopsy:

Labeled as '1': No tumor present (0/2)

Extranodal tumor extension

Labeled as '2': No tumor present (0/4)

Extranodal tumor extension

Labeled as '4sa': No tumor present (0/7)

Extranodal tumor extension

Labeled as '4sb': No tumor present (0/4)

Labeled as '5': No tumor present (0/2)

Labeled as '6': No tumor present (0/13)

Labeled as '7': No tumor present (0/2)

Labeled as '8a': No tumor present (0/2)

Labeled as '8p': No tumor present (0/1)

Labeled as '9': No tumor present (0/9)

Labeled as '10': No lymphoid tissue

Labeled as '11p': No tumor present (0/1)

Labeled as '11d': No tumor present (0/1)

Labeled as '12': No tumor present (0/2)

Labeled as '11o': No tumor present (0/3)

Reviewed By:	DBR Reviewed: 10/9/12	

lw 9/20/12

Source: NCI Genomic Data Commons file 2f9512ae-c4d4-47c5-97c4-6342c19f3269 (TCGA-HU-A4GN.E488C3D3-9801-4D1A-BAE8-DB8AC6A3DD70.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).